Somatic mutation profile of tumor specimen TCGA-AA-3715-01A (aliquot TCGA-AA-3715-01A-01W-0900-09) from TCGA case TCGA-AA-3715, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenosquamous carcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 77.8 years (28,428 days).
Specimen TCGA-AA-3715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c1ba550-574e-4bc3-a564-87e52ba76961.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3715-10A (Blood Derived Normal), aliquot TCGA-AA-3715-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a7104af-8c37-4492-9e72-f1e3f379e103

The open-access MAF lists 2,640 somatic variants for this specimen: 2,053 protein-altering or splice-affecting, 538 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,426, Silent 538, Frame Shift Del 429, Nonsense Mutation 76, Frame Shift Ins 48, Splice Site 43, Intron 19, Splice Region 14, RNA 13, In Frame Del 11, 3'UTR 10, 5'Flank 3.

Variants (750 of 2,640; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.4113del p.K1371Nfs*65 | Frame Shift Del (DEL) | VAF 39/130 reads (30%) | catalogued as rs752661599, COSV100863757; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CARD11 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748839211, COSV67798212; called by muse, mutect2, varscan2
- CENPF | c.5920del p.T1974Pfs*11 | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | catalogued as rs757531591; ClinVar: pathogenic; called by mutect2, varscan2
- CREBBP | c.5219A>G p.H1740R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1567263724, COSV52132378; ClinVar: likely pathogenic; called by muse, mutect2
- HMBS | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057521126, CM970737, COSV53829382; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNJ2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473384, CM013394, COSV54662748; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 30/61 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as rs866982998, CM1413284; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.969dup p.V324Sfs*8 | Frame Shift Ins (INS) | VAF 25/160 reads (16%) | catalogued as rs587783865; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 40/214 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PLD1 | c.2882+2T>C p.X961_splice | Splice Site (SNP) | VAF 31/212 reads (15%) | catalogued as rs1085307450, COSV100577596; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PROKR2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138672528, CM083838; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RIMS1 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 32/131 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2, varscan2
- RPGRIP1 | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as rs759940113, COSV52852131; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SLC12A6 | c.337C>T p.R113* (on ENST00000354181 / NM_001365088.1; = p.R62* on NM_005135.2) | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as rs1054429141, COSV51628401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC17A5 | c.349del p.Y117Mfs*17 | Frame Shift Del (DEL) | VAF 25/205 reads (12%) | catalogued as rs772039085; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SLC18A2 | c.711del p.F238Sfs*48 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs762879329, COSV53693545; ClinVar: likely pathogenic; called by mutect2, varscan2
- SMPD1 | c.996del p.F333Sfs*52 | Frame Shift Del (DEL) | VAF 21/140 reads (15%) | catalogued as rs387906289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STXBP1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1064794322, COSV64813096; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.7440del p.A2481Pfs*7 | Frame Shift Del (DEL) | VAF 25/48 reads (52%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.2525C>T p.T842I | Missense Mutation (SNP) | VAF 71/1284 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs775695540, COSV55301886; called by muse, mutect2
- A2ML1 | c.2774C>T p.A925V | Missense Mutation (SNP) | VAF 109/244 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs868280801, COSV55287959; called by muse, varscan2
- AARS1 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99933179; called by muse, mutect2
- ABCA12 | c.4636C>T p.R1546C (on ENST00000272895 / NM_173076.3; = p.R1228C on NM_015657.3) | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs13401480, COSV55963501; called by muse, mutect2, varscan2
- ABCA4 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV64675453; called by muse, mutect2, varscan2
- ABCA7 | c.4598C>T p.S1533L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs776920026, COSV54026755; called by muse, mutect2, varscan2
- ABCB5 | c.2819G>A p.G940E (on ENST00000404938 / NM_001163941.2; = p.G495E on NM_178559.6) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV51714719; called by muse, mutect2, varscan2
- ABCB5 | c.3770A>G p.Q1257R (on ENST00000404938 / NM_001163941.2; = p.Q812R on NM_178559.6) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV51714735; called by muse, mutect2, varscan2
- ABCC1 | c.3708C>G p.Y1236* | Nonsense Mutation (SNP) | VAF 29/129 reads (22%) | catalogued as COSV60689731; called by muse, mutect2, varscan2
- ABCD2 | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 176/290 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58053192; called by muse, mutect2, varscan2
- ABCG4 | c.1204A>T p.I402F | Missense Mutation (SNP) | VAF 80/303 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV56644678; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.955A>G p.K319E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV68344270; called by muse, mutect2, varscan2
- ABL1 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as rs1371645607, COSV59326663; called by muse, mutect2, varscan2
- ABLIM1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs756279625, COSV53306820; called by muse, mutect2, varscan2
- ABLIM3 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 111/184 reads (60%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV58645763; called by muse, mutect2, varscan2
- AC008676.3 | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 178/401 reads (44%) | catalogued as COSV56637295; called by muse, mutect2, varscan2
- AC011462.1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs764481217, COSV99524415; called by muse, mutect2, varscan2
- AC098582.1 | c.753A>C p.E251D | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1184238609, COSV52022411; called by muse, mutect2, varscan2
- AC127029.3 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as rs371051668, COSV60111188; called by muse, mutect2, varscan2
- ACAD11 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs780673385, COSV53898953; called by muse, mutect2, varscan2
- ACAN | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100719299, COSV61364611; called by muse, mutect2, varscan2
- ACAT2 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV58459698; called by muse, mutect2, varscan2
- ACKR4 | c.845A>G p.D282G | Missense Mutation (SNP) | VAF 76/1070 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99391535; called by muse, mutect2
- ACSBG1 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs554607936, COSV51908449; called by muse, mutect2, varscan2
- ACTA1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.349); catalogued as rs1375723160, COSV64203726; called by muse, varscan2
- ACTA2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs397516684, CM145697, COSV56515587; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTB | c.395T>C p.M132T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.315); catalogued as COSV59319766; called by muse, mutect2, varscan2
- ACTL7A | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.404); catalogued as rs144590040; called by muse, mutect2, varscan2
- ACTR1B | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs372634354; called by muse, mutect2, varscan2
- ADAL | c.651dup p.E218Rfs*11 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as rs778831705; called by mutect2, varscan2
- ADAM10 | c.57T>A p.G19= | Splice Region (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99545528; called by muse, varscan2
- ADAM18 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs765835846, COSV55844299; called by muse, mutect2, varscan2
- ADAM18 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV55850845; called by muse, mutect2, varscan2
- ADAM30 | c.1955G>A p.C652Y | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101023759; called by muse, mutect2
- ADAM32 | c.1293A>T p.K431N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV65951495; called by muse, mutect2, varscan2
- ADAM7 | c.963T>C p.D321= | Splice Region (SNP) | VAF 27/69 reads (39%) | catalogued as COSV51543168; called by muse, mutect2, varscan2
- ADAMTS4 | c.472dup p.A158Gfs*2 | Frame Shift Ins (INS) | VAF 8/94 reads (9%) | catalogued as rs1558077955; called by mutect2, pindel
- ADAMTS5 | c.2063C>G p.T688S | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV53181419; called by muse, mutect2, varscan2
- ADAMTS8 | c.803T>A p.V268E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57295223; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1103T>G p.I368S | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52819756; called by muse, mutect2, varscan2
- ADAR | c.22T>A p.S8T | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as rs1233371400, COSV52717908; called by muse, mutect2, varscan2
- ADCK1 | c.1319G>A p.G440D | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs140999497; called by muse, mutect2, varscan2
- ADCY1 | c.1673A>G p.Y558C | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1335223928, COSV52038432; called by muse, mutect2, varscan2
- ADCY2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs1267251314, COSV100601562; called by muse, mutect2
- ADCY2 | c.1492T>G p.L498V | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57884840; called by muse, mutect2, varscan2
- ADCY7 | c.3061C>T p.R1021* | Nonsense Mutation (SNP) | VAF 21/127 reads (17%) | catalogued as rs768517386, COSV54268745; called by muse, mutect2, varscan2
- ADCY9 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); catalogued as COSV53571553; called by muse, mutect2
- ADD2 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 157/515 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.372); catalogued as rs758903259, COSV52460970; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB2 | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.263); catalogued as rs774040499, COSV57073908; called by muse, mutect2, varscan2
- ADGRD1 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as COSV55441027; called by muse, mutect2, varscan2
- ADGRF4 | c.1324T>C p.C442R | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51954744; called by muse, mutect2, varscan2
- ADGRF5 | c.1684G>A p.V562I | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV51937041; called by muse, mutect2, varscan2
- ADGRG6 | c.1850T>C p.V617A | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755737485, COSV51596241; called by muse, mutect2, varscan2
- ADGRG7 | c.1989del p.V664Ffs*4 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | catalogued as rs746519567; called by mutect2, pindel
- ADGRL3 | c.1772C>T p.A591V (on ENST00000506720 / NM_001322402.2; = p.A523V on NM_015236.6) | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs1199773414, COSV72231238; called by muse, mutect2, varscan2
- ADH6 | c.652G>C p.A218P | Missense Mutation (SNP) | VAF 153/550 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52956942; called by muse, mutect2, varscan2
- AGAP1 | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV58332711; called by muse, mutect2, varscan2
- AGAP1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs373781245; called by muse, varscan2
- AGAP1 | c.1669A>G p.I557V (on ENST00000304032 / NM_001037131.3; = p.I504V on NM_014914.5) | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.511); catalogued as COSV58327405; called by muse, varscan2
- AGAP1 | c.1708G>A p.A570T (on ENST00000304032 / NM_001037131.3; = p.A517T on NM_014914.5) | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs867640037, COSV100363744; called by muse, varscan2
- AGFG2 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53546167; called by muse, mutect2, varscan2
- AGK | c.478T>G p.L160V | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); catalogued as COSV62595213; called by muse, mutect2
- AGL | c.2373G>T p.K791N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV54055539; called by muse, mutect2, varscan2
- AGO2 | c.824T>C p.M275T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV55049709; called by muse, mutect2
- AGXT2 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1240390538, COSV51483644; called by muse, mutect2
- AHNAK | c.2944G>A p.V982I | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs757168510, COSV57221574; called by muse, mutect2, varscan2
- AHNAK2 | c.10537C>T p.Q3513* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs1234657799, COSV60921892; called by muse, mutect2, varscan2
- AHNAK2 | c.7471C>T p.P2491S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs764399346, COSV60921919; called by muse, mutect2, varscan2
- AHNAK2 | c.6834G>T p.E2278D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.391); catalogued as COSV60921924; called by muse, mutect2
- AHNAK2 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.196); catalogued as rs755779262, COSV60921937; called by muse, mutect2, varscan2
- AHR | c.1379T>G p.M460R | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV54124785; called by muse, mutect2, varscan2
- AHSG | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 127/450 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV99889837; called by muse, mutect2
- AIMP2 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs764368950, COSV52241171; called by muse, mutect2, varscan2
- AIMP2 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.237); catalogued as rs75895975; called by muse, mutect2
- AKAP13 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV63464358; called by muse, mutect2, varscan2
- AKAP13 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV63464361; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKT1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs549370342, COSV62574674; called by muse, mutect2
- AL121899.2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs774924175, COSV67351439; called by muse, mutect2, varscan2
- ALAS2 | c.1546C>A p.L516M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58191995; called by muse, mutect2, varscan2
- ALDH18A1 | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100973054; called by muse, mutect2
- ALDH1A3 | c.346-1G>A p.X116_splice | Splice Site (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100320231; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs778623472, COSV56735668; called by mutect2, varscan2
- ALDH6A1 | c.329A>C p.Q110P | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.46); catalogued as COSV63246806; called by muse, mutect2, varscan2
- ALG10B | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58143316; called by muse, mutect2
- ALG9 | c.1669G>A p.E557K (on ENST00000614444 / NM_001352418.1; = p.E564K on NM_024740.2) | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV67644921, COSV67645264; called by muse, mutect2, varscan2
- ALK | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs1430324218, COSV66578629; called by muse, mutect2, varscan2
- ALPK1 | c.3063del p.K1021Nfs*18 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs1159828137; called by mutect2, varscan2
- ALPK3 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs1001137642, COSV51934009; called by muse, mutect2, varscan2
- ALS2 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as COSV51889601; called by muse, mutect2, varscan2
- AMOTL1 | c.1103del p.P368Lfs*5 | Frame Shift Del (DEL) | VAF 79/380 reads (21%) | catalogued as COSV54417863; called by mutect2, pindel, varscan2
- AMPD2 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV56649149; called by muse, mutect2, varscan2
- AMPD3 | c.1690G>A p.A564T (on ENST00000396553 / NM_001025389.2; = p.A573T on NM_000480.3) | Missense Mutation (SNP) | VAF 105/356 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1286765464, COSV101158079; called by muse, mutect2, varscan2
- ANGPT2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs936575985, COSV57335765; called by muse, mutect2, varscan2
- ANGPT4 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67920923; called by muse, mutect2, varscan2
- ANK2 | c.4018A>G p.I1340V | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.646); catalogued as COSV99999640; called by muse, mutect2, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 92/423 reads (22%) | catalogued as rs370637835; called by mutect2, varscan2
- ANKRD13A | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs1481217387, COSV55677303; called by muse, mutect2, varscan2
- ANKRD17 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV58224019; called by muse, mutect2, varscan2
- ANKRD50 | c.1939G>T p.A647S | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV72385934; called by muse, mutect2, varscan2
- ANKRD55 | c.1009del p.Q337Rfs*111 | Frame Shift Del (DEL) | VAF 46/166 reads (28%) | catalogued as COSV100591587; called by mutect2, pindel, varscan2
- ANKRD6 | c.2000T>G p.L667R (on ENST00000339746 / NM_001242809.2; = p.L662R on NM_014942.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV60233704; called by muse, mutect2, varscan2
- ANKZF1 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99850233; called by muse, mutect2, varscan2
- ANP32D | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 105/317 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs570494201, COSV56980715; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 35/84 reads (42%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- AOC3 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV53827828; called by muse, mutect2, varscan2
- AP2B1 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV52001179; called by muse, mutect2, varscan2
- AP2M1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV53049110; called by muse, mutect2, varscan2
- APAF1 | c.1655G>A p.G552E (on ENST00000551964 / NM_181861.2; = p.G541E on NM_001160.3) | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59662435; called by muse, mutect2, varscan2
- APBA1 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs910507912, COSV99595396; called by muse, mutect2, varscan2
- APBB1 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV54972438; called by muse, mutect2, varscan2
- APC | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV57362041; called by muse, mutect2, varscan2
- APEX1 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51658327; called by muse, mutect2, varscan2
- APLNR | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57242974; called by muse, mutect2, varscan2
- APLP2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1212536922, COSV53842237; called by muse, mutect2
- APPL1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs745495066, COSV55701912; called by muse, mutect2, varscan2
- AQP11 | c.229T>C p.W77R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as COSV57992839; called by muse, varscan2
- ARAP3 | c.1600C>A p.L534M | Missense Mutation (SNP) | VAF 162/827 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53352395; called by muse, mutect2, varscan2
- ARHGAP11B | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759843396, COSV70288411; called by mutect2, varscan2
- ARHGAP17 | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.42); catalogued as COSV51509658; called by muse, mutect2, varscan2
- ARHGAP20 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV52814899; called by muse, mutect2, varscan2
- ARHGAP27 | c.1352G>A p.S451N (on ENST00000428638 / NM_001282290.1; = p.S110N on NM_199282.3) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV65358187; called by muse, mutect2, varscan2
- ARHGAP28 | c.1307T>C p.L436P (on ENST00000383472 / NM_001366230.1; = p.L277P on NM_001010000.3) | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1214308156, COSV51632708, COSV51641871; called by muse, mutect2, varscan2
- ARHGAP36 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.971); catalogued as COSV52269234; called by muse, mutect2, varscan2
- ARHGEF25 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs61935728, COSV54088483; called by muse, mutect2, varscan2
- ARHGEF26 | c.1948G>A p.V650I | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.293); catalogued as COSV62848955; called by muse, mutect2, varscan2
- ARHGEF26 | c.2447T>C p.V816A | Missense Mutation (SNP) | VAF 113/499 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62848965; called by muse, mutect2, varscan2
- ARHGEF5 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 306/1531 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as rs1227303814, COSV50213530; called by muse, mutect2, varscan2
- ARID2 | c.521A>G p.D174G | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57609403; called by muse, mutect2, varscan2
- ARID2 | c.3952C>T p.Q1318* | Nonsense Mutation (SNP) | VAF 65/146 reads (45%) | catalogued as COSV57600698; called by muse, mutect2, varscan2
- ARID5B | c.2032C>A p.L678I | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); catalogued as COSV54425234; called by muse, mutect2, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARMC12 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99849303; called by muse, mutect2, varscan2
- ARMC3 | c.2064del p.E689Kfs*5 | Frame Shift Del (DEL) | VAF 25/111 reads (23%) | catalogued as rs1564406625, COSV53062369; called by mutect2, pindel, varscan2
- ARNTL2 | c.1910A>G p.*637Wext*37 | Nonstop Mutation (SNP) | VAF 7/102 reads (7%) | catalogued as COSV99667501; called by muse, mutect2
- ARPC5 | c.188del p.P63Lfs*9 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | catalogued as rs1558122795, COSV54172267; called by mutect2, pindel, varscan2
- ART1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV51705753; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 58/152 reads (38%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASAH1 | c.1217A>G p.D406G | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs373012279, COSV50503140; called by muse, mutect2, varscan2
- ASB2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100279216; called by muse, mutect2
- ASCC3 | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527410635, COSV64975373; called by muse, mutect2, varscan2
- ASF1B | c.128T>G p.I43S | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV54616518; called by muse, mutect2, varscan2
- ASIC3 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs374555174, COSV52524212; called by muse, mutect2, varscan2
- ASNSD1 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53624277; called by muse, mutect2, varscan2
- ASPM | c.2942C>T p.T981I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs763886024, COSV54123796, COSV99659493; called by muse, varscan2
- ASPN | c.923T>C p.L308S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65016374; called by muse, varscan2
- ASXL1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144349534; called by muse, mutect2, varscan2
- ASZ1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs766060538, COSV52912490; called by muse, varscan2
- ATAD2 | c.2993A>G p.H998R | Missense Mutation (SNP) | VAF 99/298 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.267); catalogued as rs748172134, COSV54883714; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 59/142 reads (42%) | catalogued as rs746676748; called by mutect2, varscan2
- ATL1 | c.927C>A p.S309R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV63296900; called by muse, mutect2, varscan2
- ATP10B | c.364T>G p.L122V | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.357); catalogued as COSV58779762; called by muse, mutect2, varscan2
- ATP10D | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759172595, COSV56710131; called by muse, mutect2, varscan2
- ATP13A3 | c.1402T>C p.Y468H | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV55467136; called by muse, mutect2, varscan2
- ATP1A4 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 120/328 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780442630, COSV63626311; called by muse, mutect2, varscan2
- ATP5F1C | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.119); catalogued as COSV59622248; called by muse, varscan2
- ATP6V0A4 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100022641; called by muse, mutect2
- ATP6V0D2 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53416202; called by muse, varscan2
- ATP7B | c.1605G>T p.E535D | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54440844; called by muse, mutect2, varscan2
- ATP8A2 | c.2521A>T p.N841Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV99679959; called by muse, mutect2, varscan2
- ATP8A2 | c.2668T>C p.Y890H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99679961; called by muse, mutect2, varscan2
- ATXN2 | c.1774C>T p.P592S (on ENST00000550104; = p.P432S on NM_002973.4) | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.091); catalogued as COSV66484663; called by muse, mutect2, varscan2
- ATXN7 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs758357287, COSV55753114; called by muse, mutect2, varscan2
- AVIL | c.1745T>C p.V582A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV57682745; called by muse, mutect2, varscan2
- AVPR1A | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV54546770; called by muse, mutect2, varscan2
- B4GALNT1 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV57543749; called by muse, mutect2, varscan2
- B4GALT2 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs753720865, COSV58844797; called by muse, mutect2, varscan2
- BAG2 | c.631A>C p.N211H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV58098606; called by muse, mutect2, varscan2
- BARHL1 | c.748T>C p.Y250H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55038327; called by muse, mutect2, varscan2
- BAZ2B | c.3862C>T p.R1288C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs758175588, COSV54274845; called by muse, mutect2
- BAZ2B | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.028); catalogued as COSV100600620; called by muse, mutect2
- BBS7 | c.1520A>G p.N507S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.826); catalogued as COSV52657961; called by muse, mutect2, varscan2
- BBX | c.1700A>C p.E567A | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV57889224; called by muse, mutect2, varscan2
- BCKDK | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs766922526, COSV54890747; called by muse, mutect2, varscan2
- BCL6B | c.546del p.S183Vfs*20 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as COSV53426596; called by mutect2, pindel, varscan2
- BCL9 | c.3550C>A p.P1184T | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as COSV52347340; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs768244116; called by mutect2, pindel
- BCR | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as rs201579887, COSV59933659; called by muse, mutect2, varscan2
- BCR | c.2243C>T p.T748M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.627); catalogued as rs189814131, COSV59932082; called by muse, mutect2
- BICDL1 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1358926409, COSV66908387; called by muse, mutect2, varscan2
- BMI1 | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64959338; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 158/214 reads (74%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BNC1 | c.2264G>A p.C755Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162514280, COSV61758304; called by muse, mutect2, varscan2
- BORA | c.1619G>A p.G540D (on ENST00000613797; = p.G465D on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/541 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64695565; called by muse, mutect2, varscan2
- BRAF | c.613A>C p.K205Q | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV56268820; called by muse, mutect2, varscan2
- BRCA1 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV58794475; called by muse, mutect2, varscan2
- BRCA2 | c.2495A>G p.E832G | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV66453659, COSV66457801; called by muse, mutect2, varscan2
- BRD1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.116); catalogued as COSV53459496; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 25/100 reads (25%) | catalogued as rs749043197; called by mutect2, varscan2
- BRD8 | c.399C>G p.H133Q | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.24); catalogued as COSV50157872; called by muse, mutect2, varscan2
- BRSK1 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV58668204; called by muse, mutect2, varscan2
- BSN | c.5984A>G p.N1995S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs774448685, COSV56522739; called by muse, mutect2
- BTBD11 | c.2219C>T p.A740V (on ENST00000280758 / NM_001018072.2; = p.A277V on NM_001017523.2) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV55030019; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | catalogued as rs752512017; called by mutect2, varscan2
- BTN1A1 | c.1106A>G p.D369G | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99764165; called by muse, mutect2
- C10orf90 | c.299T>C p.F100S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV52958971; called by muse, mutect2, varscan2
- C11orf53 | c.164-1G>T p.X55_splice | Splice Site (SNP) | VAF 65/258 reads (25%) | catalogued as COSV54722150; called by muse, mutect2, varscan2
- C12orf42 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs774618246, COSV59386564; called by muse, mutect2, varscan2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 52/108 reads (48%) | catalogued as rs780875081; called by mutect2, varscan2
- C14orf93 | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV54441923; called by muse, mutect2, varscan2
- C19orf44 | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55613211; called by muse, mutect2, varscan2
- C1QTNF3 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 24/413 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV51469320; called by muse, mutect2
- C1orf189 | c.149G>T p.R50M | Missense Mutation (SNP) | VAF 130/608 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV63891120; called by muse, mutect2, varscan2
- C1orf194 | c.307A>G p.T103A (on ENST00000369948 / NM_001245025.3; = p.T91A on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV64050041; called by muse, mutect2, varscan2
- C1orf87 | c.1603C>A p.L535I | Missense Mutation (SNP) | VAF 115/453 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV64597881; called by muse, mutect2, varscan2
- C2CD6 | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV99631872; called by muse, mutect2, varscan2
- C2orf16 | c.4312G>A p.A1438T | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV62676960; called by muse, mutect2, varscan2
- C2orf80 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 47/198 reads (24%) | catalogued as rs772328176, COSV58017593; called by muse, mutect2, varscan2
- C3 | c.4889A>G p.H1630R | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55576629; called by muse, mutect2, varscan2
- C9orf43 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs573828696, COSV55913261; called by muse, mutect2
- CA8 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV58773235; called by muse, mutect2, varscan2
- CACNA1A | c.2356C>T p.R786* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as COSV64204504; called by muse, mutect2, varscan2
- CACNA1C | c.4875G>T p.Q1625H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV100215225; called by muse, mutect2, varscan2
- CACNA1S | c.3686G>A p.R1229H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs774416016, COSV62939289; called by muse, mutect2, varscan2
- CACNA2D1 | c.2893T>C p.F965L (on ENST00000356253 / NM_001366867.1; = p.F953L on NM_000722.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs745875905, COSV62385266; called by muse, mutect2, varscan2
- CACNB3 | c.1361A>C p.D454A | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV99974667; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 38/170 reads (22%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CAD | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 34/622 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as COSV99254395; called by muse, mutect2
- CADM1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as rs201626870, COSV59008985; called by muse, mutect2, varscan2
- CAMSAP1 | c.2395G>T p.A799S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.035); catalogued as COSV56725119, COSV56726219; called by muse, mutect2, varscan2
- CAMSAP2 | c.3682C>T p.R1228C (on ENST00000236925 / NM_001297707.2; = p.R1217C on NM_203459.3) | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749701945, COSV52667116; called by muse, mutect2, varscan2
- CANX | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs755452646, COSV56005509; called by muse, mutect2, varscan2
- CAP2 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 229/502 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs372852769; called by muse, mutect2, varscan2
- CASP8 | c.1229T>C p.V410A (on ENST00000432109 / NM_033355.3; = p.V427A on NM_001228.4) | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV51854870; called by muse, mutect2, varscan2
- CATSPERD | c.809-2A>G p.X270_splice | Splice Site (SNP) | VAF 13/119 reads (11%) | catalogued as rs1292695793, COSV101062372; called by muse, mutect2, varscan2
- CCDC102A | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs750089033, COSV50777621; called by muse, mutect2, varscan2
- CCDC102B | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100102163; called by muse, mutect2
- CCDC105 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as COSV52964730; called by muse, mutect2, varscan2
- CCDC127 | c.522del p.C174* | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | catalogued as COSV57256796; called by mutect2, pindel, varscan2
- CCDC170 | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.423); catalogued as rs376388158; called by muse, mutect2, varscan2
- CCDC170 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV53337121; called by muse, mutect2, varscan2
- CCDC34 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.565); catalogued as COSV58725747, COSV58726475; called by muse, mutect2, varscan2
- CCDC59 | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50259954, COSV50260213; called by muse, mutect2, varscan2
- CCDC62 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 135/377 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs569908909, COSV53435582; called by muse, mutect2, varscan2
- CCDC80 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV52818383; called by muse, mutect2, varscan2
- CCIN | c.1315A>G p.I439V | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.558); catalogued as COSV100631697; called by muse, mutect2
- CCS | c.250+1G>A p.X84_splice | Splice Site (SNP) | VAF 39/108 reads (36%) | catalogued as rs746825506, COSV100039741; called by muse, mutect2, varscan2
- CD163L1 | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 198/475 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV100550342, COSV58020178; called by muse, mutect2, varscan2
- CD207 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs782778641, COSV69652377; called by muse, mutect2
- CD37 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60544882; called by muse, mutect2, varscan2
- CD93 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs763943573, COSV55666935; called by muse, mutect2, varscan2
- CD93 | c.440A>T p.D147V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV55666950; called by muse, mutect2
- CDC25B | c.710T>A p.L237H (on ENST00000245960 / NM_021873.3; = p.L223H on NM_004358.4) | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.855); catalogued as COSV55658211; called by muse, mutect2, varscan2
- CDH11 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51767979, COSV51769087; called by muse, mutect2, varscan2
- CDH13 | c.342del p.D116Tfs*31 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs1567763530, COSV51808407; called by mutect2, pindel, varscan2
- CDH19 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 38/111 reads (34%) | catalogued as rs778178307, COSV50971600; called by muse, varscan2
- CDK19 | c.510A>C p.K170N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60451176; called by muse, mutect2, varscan2
- CEBPZ | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1191712751, COSV52207333; called by muse, mutect2, varscan2
- CELF1 | c.1459T>C p.*487Rext*9 (on ENST00000358597 / NM_001376422.1; = p.*483Rext*9 on NM_006560.4 and 10 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 83/622 reads (13%) | catalogued as COSV100136645; called by muse, mutect2, varscan2
- CENPC | c.1723del p.T575Lfs*21 | Frame Shift Del (DEL) | VAF 48/176 reads (27%) | catalogued as rs1560431351; called by mutect2, pindel, varscan2
- CENPC | c.1479A>T p.E493D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV56624703, COSV99894381; called by muse, mutect2
- CENPH | c.435+2T>C p.X145_splice | Splice Site (SNP) | VAF 44/150 reads (29%) | catalogued as COSV51585833; called by muse, mutect2, varscan2
- CENPJ | c.1026A>T p.L342F | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV67883780; called by muse, mutect2, varscan2
- CENPN | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746494487, COSV100001463, COSV55141857; called by muse, mutect2, varscan2
- CENPQ | c.125del p.N42Ifs*5 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | catalogued as rs756590976; called by mutect2, varscan2
- CENPU | c.380del p.K127Sfs*31 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | catalogued as rs34873798; called by mutect2, pindel, varscan2
- CEP126 | c.1581A>G p.I527M | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as COSV54827869; called by muse, mutect2, varscan2
- CEP162 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as rs1413364753, COSV100002366; called by muse, mutect2
- CEP170 | c.3310C>T p.R1104C | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1458488215, COSV60506058; called by muse, mutect2
- CEP170 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as rs868090099, COSV63731759; called by muse, mutect2, varscan2
- CEP290 | c.4246C>T p.R1416C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776812442, COSV58353725; called by muse, mutect2, varscan2
- CEP70 | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99388805; called by muse, mutect2
- CFAP100 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs138829390; called by muse, mutect2, varscan2
- CFAP251 | c.998+2T>C p.X333_splice | Splice Site (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99995699; called by muse, mutect2, varscan2
- CFAP69 | c.806A>G p.E269G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV60186909; called by muse, mutect2, varscan2
- CFAP91 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762187278, COSV56338863; called by muse, mutect2, varscan2
- CHAD | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV51973372; called by muse, mutect2, varscan2
- CHCHD5 | c.132C>A p.C44* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV61424622; called by muse, mutect2, varscan2
- CHD3 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 119/488 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV57877674; called by muse, mutect2, varscan2
- CHD4 | c.3301G>A p.A1101T (on ENST00000357008 / NM_001363606.2; = p.A1114T on NM_001273.5) | Missense Mutation (SNP) | VAF 323/1023 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58902836; called by muse, mutect2, varscan2
- CHD6 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 177/737 reads (24%) | catalogued as COSV58559571; called by muse, mutect2, varscan2
- CHEK1 | c.1408A>T p.K470* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV54024660; called by muse, mutect2, varscan2
- CHFR | c.1771G>T p.D591Y (on ENST00000432561 / NM_001161345.1; = p.D550Y on NM_018223.2) | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57176266; called by muse, mutect2, varscan2
- CHGB | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs200903465, COSV66761102; called by muse, mutect2, varscan2
- CHL1 | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV56598178; called by muse, mutect2, varscan2
- CHRM1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs773788891, COSV61006856; called by muse, mutect2, varscan2
- CHRM2 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57778320; called by muse, mutect2, varscan2
- CHRM2 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV57784952; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 50/85 reads (59%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNB2 | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100872534; called by muse, mutect2
- CHST10 | c.742A>T p.N248Y | Missense Mutation (SNP) | VAF 119/422 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV51806326; called by muse, mutect2, varscan2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 57/198 reads (29%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CHTOP | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV64155365; called by muse, mutect2, varscan2
- CIC | c.3937C>T p.R1313W | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as rs773220927, COSV50622418; called by mutect2, varscan2
- CIITA | c.3358C>A p.L1120M | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60859641; called by muse, mutect2, varscan2
- CIZ1 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.146); catalogued as COSV52973122; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | catalogued as rs752250702; called by mutect2, varscan2
- CLBA1 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.048); catalogued as COSV101120966; called by muse, mutect2, varscan2
- CLDN10 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV65298423; called by muse, mutect2, varscan2
- CLECL1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 82/150 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); catalogued as COSV59931817; called by muse, mutect2, varscan2
- CLIP3 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV62112903; called by muse, mutect2, varscan2
- CLP1 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 43/376 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57055113; called by muse, mutect2, varscan2
- CLPTM1 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs752663268, COSV61612413; called by muse, mutect2, varscan2
- CLSTN3 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 217/590 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56938383; called by muse, mutect2, varscan2
- CLYBL | c.818A>G p.H273R | Missense Mutation (SNP) | VAF 121/363 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59224771; called by muse, mutect2, varscan2
- CMAS | c.353A>T p.D118V | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57557034; called by muse, mutect2, varscan2
- CNGA1 | c.1571C>A p.A524E | Missense Mutation (SNP) | VAF 125/476 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV62055408; called by muse, mutect2, varscan2
- CNMD | c.71del p.P24Rfs*6 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs768157613; called by mutect2, varscan2
- CNNM1 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs370414041; called by muse, varscan2
- CNOT1 | c.4180C>T p.R1394C | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55319614; called by muse, mutect2, varscan2
- CNTN1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770683180, COSV61639340; called by muse, mutect2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.246T>A p.Y82* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100662607; called by muse, mutect2
- CNTNAP3 | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV52671203; called by muse, mutect2
- COL11A1 | c.3213T>G p.I1071M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV62189621; called by muse, mutect2, varscan2
- COL11A1 | c.1848T>C p.G616= | Splice Region (SNP) | VAF 11/36 reads (31%) | catalogued as COSV62189629; called by muse, mutect2, varscan2
- COL12A1 | c.3400G>C p.V1134L | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV100485392; called by muse, mutect2
- COL17A1 | c.3011C>T p.P1004L | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs777502825, COSV62227356; called by muse, varscan2
- COL1A2 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.394); catalogued as COSV51961861; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 6/32 reads (19%) | catalogued as rs760493024; called by mutect2, varscan2
- COL3A1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs189846410, COSV58593028; ClinVar: uncertain significance; called by muse, mutect2
- COL4A4 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV61634227; called by muse, mutect2, varscan2
- COL5A1 | c.4756A>T p.N1586Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100879475; called by muse, mutect2
- COL5A1 | c.5041G>A p.V1681I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs764763703, COSV65664604, COSV65668915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs905662421, COSV55087815, COSV55109749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.3274C>T p.P1092S | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV62030583; called by muse, mutect2, varscan2
- COLEC10 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769900711, COSV60520610; called by muse, mutect2, varscan2
- COQ2 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs1218485319, CM154314, COSV61021924; called by muse, mutect2, varscan2
- CPD | c.1390A>G p.T464A | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56714332; called by muse, mutect2, varscan2
- CPM | c.821A>G p.Q274R | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as rs1172994241, COSV58034493; called by muse, mutect2, varscan2
- CPNE1 | c.197A>G p.Y66C (on ENST00000352393; = p.Y71C on NM_003915.5) | Missense Mutation (SNP) | VAF 164/615 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58293172; called by muse, mutect2, varscan2
- CPQ | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 118/308 reads (38%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs183172032, COSV55152812; called by muse, mutect2, varscan2
- CPSF6 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57016301; called by muse, mutect2, varscan2
- CRBN | c.836-1G>A p.X279_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99214043; called by muse, mutect2, varscan2
- CREBBP | c.5087A>G p.H1696R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52132392; called by muse, mutect2, varscan2
- CRTC3 | c.700-2A>G p.X234_splice | Splice Site (SNP) | VAF 40/116 reads (34%) | catalogued as COSV99185618; called by muse, mutect2, varscan2
- CRYBG1 | c.5207del p.N1736Tfs*18 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as COSV64811040; called by pindel, varscan2
- CRYGB | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1461895852, COSV53680151; called by muse, mutect2, varscan2
- CSE1L | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs753618454, COSV53700874; called by muse, mutect2, varscan2
- CSF2RB | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs146404001, COSV53257443; called by muse, mutect2, varscan2
- CSMD1 | c.8242G>T p.G2748* (on ENST00000520002; = p.G2747* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 32/300 reads (11%) | catalogued as COSV59350588; called by muse, mutect2, varscan2
- CSMD1 | c.178T>A p.W60R | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68228451; called by muse, mutect2, varscan2
- CSMD2 | c.2989C>T p.R997W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs752575603, COSV53933679; called by muse, mutect2, varscan2
- CSMD3 | c.5126A>G p.N1709S (on ENST00000297405 / NM_001363185.1; = p.N1605S on NM_052900.3) | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52243580; called by muse, mutect2, varscan2
- CSMD3 | c.3542C>G p.P1181R (on ENST00000297405 / NM_001363185.1; = p.P1077R on NM_052900.3) | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52243593; called by muse, mutect2, varscan2
- CSNK1E | c.799T>G p.S267A | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.014); catalogued as rs1395260062, COSV100724963; called by muse, mutect2
- CSNK2A2 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99345136; called by muse, mutect2
- CSRP1 | c.505G>T p.G169* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | catalogued as COSV60637565; called by muse, mutect2, varscan2
- CTAGE15 | c.893A>G p.N298S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs1477545036; called by mutect2, varscan2
- CTNNA3 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65602625; called by muse, mutect2, varscan2
- CTNND2 | c.2808C>A p.D936E | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV58906500; called by muse, mutect2, varscan2
- CTPS1 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV65453266; called by muse, mutect2, varscan2
- CTSL | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58246110, COSV58246800; called by muse, mutect2, varscan2
- CTSS | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs946440063, COSV64566656; called by muse, mutect2, varscan2
- CTSZ | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs201081854; called by muse, mutect2, varscan2
- CTTNBP2 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV50424317; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | catalogued as rs745836350; called by mutect2, varscan2
- CYB5RL | c.900del p.R300Sfs*25 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as COSV55276717; called by mutect2, pindel
- CYP11B1 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV52828849; called by muse, mutect2
- CYP2A13 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs745929748, COSV100387017, COSV57838994; called by muse, mutect2, varscan2
- CYP2E1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs563043306, COSV53314350; called by muse, mutect2
- CYP2F1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 59/226 reads (26%) | catalogued as rs1349532357, COSV58527253; called by muse, mutect2, varscan2
- CYP51A1 | c.998del p.L333Wfs*13 | Frame Shift Del (DEL) | VAF 41/305 reads (13%) | catalogued as rs1563179322; called by mutect2, pindel, varscan2
- DAAM1 | c.2804C>A p.A935D | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62837945; called by muse, mutect2, varscan2
- DBF4B | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.421); catalogued as rs753649695, COSV59262045; called by muse, mutect2, varscan2
- DCAF4L1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV60786317; called by muse, mutect2, varscan2
- DCC | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59117530; called by muse, varscan2
- DCK | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV54379168; called by muse, mutect2, varscan2
- DCST1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs775679292, COSV55058740; called by muse, mutect2, varscan2
- DCST2 | c.1523G>A p.G508D | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55050040; called by muse, mutect2, varscan2
- DCT | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV65470025; called by muse, mutect2, varscan2
- DCTN2 | c.634C>T p.R212W (on ENST00000548249 / NM_001261413.2; = p.R217W on NM_006400.4) | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs374804015; called by muse, mutect2, varscan2
- DDHD2 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV68158295; called by muse, mutect2, varscan2
- DDIAS | c.63A>G p.I21M | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs150528544; called by muse, mutect2, varscan2
- DDX11 | c.1955T>C p.V652A | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52506006, COSV52507585; called by muse, mutect2, varscan2
- DDX17 | c.1745A>T p.D582V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as COSV53248808, COSV53249161; called by muse, mutect2, varscan2
- DDX18 | c.1237T>A p.F413I | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV54307617; called by muse, mutect2, varscan2
- DDX27 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs779990675, COSV65609197; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX28 | c.1019T>C p.L340S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV60105917; called by muse, mutect2, varscan2
- DDX41 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.093); catalogued as COSV57904723; called by muse, mutect2, varscan2
- DDX49 | c.1307T>C p.I436T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55357126; called by muse, mutect2
- DDX54 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs139285972; called by muse, mutect2, varscan2
- DEDD2 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1221084504, COSV100260175; called by muse, varscan2
- DEDD2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs774239274, COSV100260177; called by muse, varscan2
- DEFB119 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as rs150495779; called by muse, mutect2, varscan2
- DENND2B | c.2610G>T p.E870D | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58205699; called by muse, mutect2, varscan2
- DENND3 | c.2219T>C p.M740T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52804372; called by muse, mutect2, varscan2
- DENND4A | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs370570206; called by muse, mutect2, varscan2
- DEPDC1 | c.488T>A p.I163K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV63958616; called by muse, mutect2, varscan2
- DEPDC5 | c.2516A>G p.K839R (on ENST00000400246; = p.K908R on NM_014662.5) | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56703715; called by muse, mutect2, varscan2
- DHFR | c.358T>C p.S120P | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV101458995; called by muse, mutect2, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 29/79 reads (37%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX16 | c.2395C>A p.L799M | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53315111; called by muse, mutect2, varscan2
- DHX30 | c.3170T>G p.L1057R (on ENST00000445061 / NM_138615.3; = p.L1018R on NM_014966.3) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53137812, COSV99274678; called by muse, mutect2, varscan2
- DHX34 | c.3157A>G p.T1053A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1021877454, COSV60896509; called by muse, mutect2, varscan2
- DHX57 | c.3121C>T p.R1041* | Nonsense Mutation (SNP) | VAF 37/140 reads (26%) | catalogued as rs143143351; called by muse, mutect2, varscan2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs749610132; called by mutect2, varscan2
- DIABLO | c.283G>A p.A95T (on ENST00000443649 / NM_001278303.1; = p.A168T on NM_019887.6) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1365705749, COSV57336928; called by muse, mutect2, varscan2
- DIP2A | c.108del p.G37Dfs*20 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1371769519; called by mutect2, pindel
- DIP2C | c.3164T>A p.I1055K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV55167958; called by muse, mutect2, varscan2
- DIP2C | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs1419537231, COSV55157254; called by muse, mutect2, varscan2
- DIRAS3 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63970490; called by muse, mutect2, varscan2
- DISP1 | c.4499A>G p.N1500S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV52661961; called by muse, mutect2, varscan2
- DKK2 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs771137309, COSV53400184; called by muse, mutect2, varscan2
- DKK4 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV55182857; called by muse, mutect2, varscan2
- DLC1 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 121/392 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as COSV52315174; called by muse, mutect2, varscan2
- DLEC1 | c.2984G>A p.G995D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.311); catalogued as COSV57302777; called by muse, mutect2
- DLEC1 | c.4847A>G p.Y1616C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100085798, COSV57176529; called by muse, mutect2
- DLG2 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.41); catalogued as COSV99712573; called by muse, mutect2, varscan2
- DLG5 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs1341431480, COSV64948835; called by muse, mutect2, varscan2
- DLGAP1 | c.2594C>A p.P865H | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59819069; called by muse, mutect2, varscan2
- DLGAP5 | c.1343G>A p.C448Y | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759488384, COSV55963504, COSV55964242, COSV99903787; called by muse, mutect2, varscan2
- DMRT2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140044845; called by muse, mutect2, varscan2
- DMXL2 | c.3898A>G p.T1300A | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99195956; called by muse, mutect2
- DNAH1 | c.5873A>G p.N1958S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV70232219; called by muse, mutect2, varscan2
- DNAH10 | c.3311A>G p.D1104G (on ENST00000409039; = p.D1043G on NM_207437.3) | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV101291949; called by muse, mutect2
- DNAH11 | c.2509A>T p.I837F | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV60966565; called by muse, mutect2, varscan2
- DNAH2 | c.10126G>A p.A3376T | Missense Mutation (SNP) | VAF 138/429 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as rs751113038, COSV66718002; called by muse, mutect2, varscan2
- DNAH3 | c.9031G>A p.A3011T | Missense Mutation (SNP) | VAF 107/315 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs746811682, COSV54500830; called by muse, mutect2, varscan2
- DNAH3 | c.5663T>C p.M1888T | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs757862756, COSV54535408; called by muse, mutect2, varscan2
- DNAH3 | c.3580C>T p.R1194* | Nonsense Mutation (SNP) | VAF 40/142 reads (28%) | catalogued as rs754109251, COSV54535434; called by muse, mutect2, varscan2
- DNAH3 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV54535460; called by muse, mutect2, varscan2
- DNAH5 | c.9947del p.P3316Lfs*22 | Frame Shift Del (DEL) | VAF 38/130 reads (29%) | catalogued as rs1206989225; called by mutect2, pindel, varscan2
- DNAH9 | c.10340G>A p.R3447H | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769435149, COSV52361311; called by muse, mutect2, varscan2
- DNAJB12 | c.1078C>T p.R360W (on ENST00000338820; = p.R326W on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs1185565262, COSV58760125; called by muse, mutect2, varscan2
- DNAJC13 | c.6544C>T p.R2182C | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs759413457, COSV53454346; called by muse, mutect2, varscan2
- DNAJC17 | c.681+2T>C p.X227_splice | Splice Site (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99591484; called by muse, mutect2, varscan2
- DNAJC5B | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV52538482; called by muse, mutect2, varscan2
- DNM1 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1476780263, COSV57853894; called by muse, mutect2
- DOCK1 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as COSV54748762; called by muse, mutect2, varscan2
- DOCK2 | c.3173A>C p.K1058T | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56963361, COSV56971995; called by muse, mutect2, varscan2
- DOCK5 | c.4633C>T p.H1545Y | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs760676476, COSV52406390; called by muse, mutect2, varscan2
- DOP1B | c.2541del p.F847Lfs*7 | Frame Shift Del (DEL) | VAF 25/93 reads (27%) | catalogued as rs750520568; called by mutect2, pindel, varscan2
- DPP3 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); catalogued as COSV64757336; called by muse, mutect2, varscan2
- DPP8 | c.1072G>T p.D358Y (on ENST00000341861 / NM_001320875.2; = p.D342Y on NM_017743.6) | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100202080; called by muse, mutect2, varscan2
- DPP8 | c.493G>A p.G165R (on ENST00000341861 / NM_001320875.2; = p.G149R on NM_017743.6) | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs1432951432, COSV55681000; called by muse, mutect2, varscan2
- DPYS | c.1158T>A p.F386L | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV59827144; called by muse, mutect2, varscan2
- DPYSL2 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60786030; called by muse, mutect2, varscan2
- DROSHA | c.28A>G p.M10V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as COSV60779146; called by muse, mutect2, varscan2
- DSG3 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV57127879; called by muse, varscan2
- DSP | c.8524C>T p.R2842C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs144850908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.16629G>T p.Q5543H (on ENST00000361203 / NM_001374722.1; = p.Q3131H on NM_015548.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV55026583; called by muse, mutect2, varscan2
- DTNA | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV52004593, COSV52013923; called by muse, varscan2
- DUOX2 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1295541055, COSV66533143; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 14/83 reads (17%) | catalogued as rs746928635; called by mutect2, pindel, varscan2
- DUSP22 | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60529027; called by muse, mutect2, varscan2
- DVL2 | c.983T>C p.M328T | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50037678; called by muse, mutect2, varscan2
- DYNC1H1 | c.3469T>G p.S1157A | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV64139351; called by muse, mutect2, varscan2
- DYNC1H1 | c.12215-1G>A p.X4072_splice | Splice Site (SNP) | VAF 27/84 reads (32%) | catalogued as COSV100794395; called by muse, mutect2, varscan2
- DYNC2I1 | c.2794G>A p.G932R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266045724, COSV68105908; called by muse, mutect2, varscan2
- DZIP1 | c.2418del p.K806Nfs*22 (on ENST00000347108; = p.K787Nfs*22 on NM_014934.5) | Frame Shift Del (DEL) | VAF 60/178 reads (34%) | catalogued as rs765594416; called by mutect2, varscan2
- E2F7 | c.2243T>A p.L748* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV59741759; called by muse, mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as rs746509911; called by mutect2, varscan2
- ECH1 | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV55489745; called by muse, mutect2, varscan2
- ECHDC1 | c.770C>T p.P257L (on ENST00000531967 / NM_001139510.1; = p.P251L on NM_001002030.2) | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs201025879, COSV58933325; called by muse, mutect2, varscan2
- EDEM2 | c.1309C>A p.L437I | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63259655; called by muse, mutect2, varscan2
- EFCAB3 | c.1139G>A p.W380* | Nonsense Mutation (SNP) | VAF 27/110 reads (25%) | catalogued as COSV59503360; called by muse, mutect2, varscan2
- EHD2 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV54409627; called by muse, mutect2, varscan2
- EID2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1390440550, COSV66810965; called by muse, mutect2, varscan2
- EIF2A | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV99855731; called by muse, mutect2
- EIF3F | c.374A>T p.D125V | Missense Mutation (SNP) | VAF 66/416 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV59142677; called by muse, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELAVL1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV60966762; called by muse, mutect2, varscan2
- ELAVL2 | c.832A>T p.I278L | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.669); catalogued as COSV56365937; called by muse, mutect2, varscan2
- ELF1 | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs865878592, COSV53500556; called by muse, mutect2, varscan2
- ELOVL1 | c.601A>G p.M201V | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60522495; called by muse, mutect2, varscan2
- ELOVL5 | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100439564; called by muse, mutect2
- ELP2 | c.1867T>C p.S623P | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60852897; called by muse, mutect2, varscan2
- EMC1 | c.946T>C p.F316L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.6); catalogued as COSV61887022; called by muse, mutect2, varscan2
- EMC2 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV55210324, COSV99624424; called by muse, mutect2, varscan2
- EML2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99839554; called by muse, mutect2, varscan2
- EML5 | c.3947G>A p.R1316H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764868671, COSV61343392; called by muse, mutect2, varscan2
- ENAM | c.3340G>T p.D1114Y | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV68536534; called by muse, mutect2, varscan2
- ENC1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); catalogued as rs1416870153, COSV100187871; called by muse, varscan2
- ENPP4 | c.628del p.I210* | Frame Shift Del (DEL) | VAF 54/231 reads (23%) | catalogued as rs756006851; called by mutect2, pindel, varscan2
- ENTPD4 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 55/381 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV62269657; called by muse, mutect2, varscan2
- EP300 | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.869); catalogued as rs1215000818, COSV54335708, COSV54338235; called by muse, mutect2, varscan2
- EPB41 | c.1850A>G p.E617G (on ENST00000343067 / NM_001166005.2; = p.E408G on NM_203342.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV58050589; called by muse, mutect2, varscan2
- EPB41 | c.2243G>A p.S748N (on ENST00000343067 / NM_001166005.2; = p.S506N on NM_004437.4) | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.568); catalogued as COSV58050603; called by muse, mutect2, varscan2
- EPB41L1 | c.1273T>C p.Y425H | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.565); catalogued as COSV52440776; called by muse, mutect2, varscan2
- EPB41L3 | c.433T>G p.L145V | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59458155; called by muse, mutect2, varscan2
- EPHA2 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776917686, COSV64453981; called by mutect2, varscan2
- EPHA4 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756184907, COSV56025592, COSV56038461; called by muse, mutect2, varscan2
- EPHA7 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV65169895; called by muse, mutect2, varscan2
- EPHB6 | c.165+1del | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs771807343; called by mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 30/103 reads (29%) | catalogued as rs768793415; called by mutect2, varscan2
- ERAL1 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 114/610 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.296); catalogued as COSV54740437; called by muse, mutect2, varscan2
- ERBB3 | c.3067G>A p.A1023T | Missense Mutation (SNP) | VAF 101/414 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV57258265; called by muse, mutect2, varscan2
- ERBB3 | c.3944G>A p.S1315N | Missense Mutation (SNP) | VAF 103/390 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99915733; called by muse, varscan2
- ERC1 | c.2206C>T p.R736* (on ENST00000360905 / NM_178040.4; = p.R708* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 55/242 reads (23%) | catalogued as rs199764310, COSV61697187; called by muse, mutect2, varscan2
- ERICH3 | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV58612329; called by muse, mutect2, varscan2
- ERVW-1 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 24/277 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.882); catalogued as COSV101423804; called by muse, mutect2
- ESPL1 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs747148602, COSV57760936, COSV99229212; called by muse, mutect2, varscan2
- ESS2 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs754673515, COSV52816630; called by muse, varscan2
- ETV1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54146646; called by muse, mutect2, varscan2
- EVC | c.2837T>C p.L946P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53835102; called by muse, mutect2, varscan2
- EXT1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65475810; called by muse, mutect2, varscan2
- EXTL3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs1367166867, COSV55039012, COSV55040717; called by muse, mutect2, varscan2
- EZH1 | c.2054T>A p.I685N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52852346; called by muse, mutect2, varscan2
- F11 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.054); catalogued as COSV53008193; called by muse, mutect2, varscan2
- FADS6 | c.949A>G p.M317V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59603125; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM120A | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs543764284, COSV99464711; called by muse, mutect2, varscan2
- FAM135B | c.4071G>T p.K1357N | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV52739067, COSV52745902, COSV99426511; called by muse, mutect2, varscan2
- FAM135B | c.2785C>T p.L929F | Missense Mutation (SNP) | VAF 101/403 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371082087; called by muse, mutect2, varscan2
- FAM135B | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50527090, COSV99356181; called by muse, mutect2
- FAM153A | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.502); catalogued as rs143733594, COSV62362183; called by muse, mutect2, varscan2
- FAM153B | c.1052C>A p.T351N (on ENST00000253490; = p.T274N on NM_001265615.1) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.607); catalogued as COSV99498722; called by mutect2, varscan2
- FAM169A | c.2008A>T p.T670S | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.053); catalogued as COSV99713572; called by muse, mutect2
- FAM47C | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs782633837, COSV63724476; called by muse, mutect2, varscan2
- FAM53A | c.988C>A p.L330I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.862); catalogued as COSV57402391; called by muse, mutect2, varscan2
- FAM83B | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV100174012; called by muse, mutect2
- FAN1 | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV62951327, COSV62952457; called by muse, mutect2, varscan2
- FANCD2 | c.2053G>A p.G685R | Missense Mutation (SNP) | VAF 104/266 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs190777319, COSV55041824; called by muse, mutect2, varscan2
- FANCG | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100734418, COSV62721336; called by muse, mutect2, varscan2
- FAT1 | c.8591T>C p.M2864T | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV71675070; called by muse, mutect2, varscan2
- FAT2 | c.2632A>G p.T878A | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.913); catalogued as COSV55824482; called by muse, mutect2, varscan2
- FAT4 | c.11207del p.L3736Yfs*8 | Frame Shift Del (DEL) | VAF 50/233 reads (21%) | catalogued as rs1314412769; called by mutect2, pindel, varscan2
- FBH1 | c.656T>A p.V219D (on ENST00000362091 / NM_178150.3; = p.V270D on NM_032807.4) | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62983464; called by muse, mutect2, varscan2
- FBN3 | c.5476G>T p.G1826C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54466221; called by muse, mutect2, varscan2
- FBXO4 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55853158; called by muse, mutect2, varscan2
- FBXO42 | c.503-1G>T p.X168_splice | Splice Site (SNP) | VAF 12/127 reads (9%) | catalogued as COSV100981621; called by muse, mutect2, varscan2
- FCGR2A | c.197G>A p.R66H (on ENST00000271450 / NM_001136219.3; = p.R65H on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750989159, COSV54838318; called by muse, mutect2, varscan2
- FCHO2 | c.2047A>G p.T683A | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.246); catalogued as COSV59275075; called by muse, mutect2, varscan2
- FERD3L | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51763443; called by muse, mutect2, varscan2
- FGA | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57398350; called by muse, mutect2, varscan2
- FGD6 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 91/312 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59694968; called by muse, mutect2, varscan2
- FGF14 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 166/377 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs199536239, COSV65935211; called by muse, mutect2, varscan2
- FGF19 | c.539G>T p.R180M | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV99594254; called by muse, mutect2
- FGF21 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.63); catalogued as rs374501551; called by muse, mutect2
- FGF7 | c.535del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs777372807; called by mutect2, varscan2
- FGFR1 | c.448C>T p.P150S (on ENST00000447712 / NM_023110.3; = p.P61S on NM_023105.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs746094709, COSV58334457; called by muse, mutect2, varscan2
- FILIP1L | c.1433G>A p.R478Q (on ENST00000354552 / NM_182909.3; = p.R238Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs776850792, COSV58772146; called by muse, mutect2, varscan2
- FLG2 | c.6554A>G p.D2185G | Missense Mutation (SNP) | VAF 316/1326 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101165588; called by mutect2, varscan2
- FLNC | c.6068A>G p.H2023R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57959943; called by muse, mutect2
- FLRT1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs752324400, COSV55357945; called by muse, mutect2
- FLRT3 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs142379846; called by muse, mutect2, varscan2
- FLT4 | c.3721G>T p.A1241S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV99985887, COSV99985904; called by muse, mutect2, varscan2
- FN1 | c.5855G>A p.R1952H | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs770932448, COSV60558165; called by muse, mutect2, varscan2
- FNIP2 | c.2585C>A p.P862H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV52442651; called by muse, mutect2, varscan2
- FNTB | c.1047del p.L350Ffs*18 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs768774237; called by mutect2, pindel
- FOXA3 | c.155del p.P52Lfs*87 | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | catalogued as rs1471315009; called by pindel, varscan2
- FOXA3 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1037761079, COSV100141218; called by muse, varscan2
- FOXM1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs375821639, COSV61206725; called by muse, mutect2, varscan2
- FOXP2 | c.2012T>A p.I671N | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV63489812; called by muse, mutect2, varscan2
- FOXP4 | c.1130C>A p.P377H (on ENST00000307972 / NM_001012426.1; = p.P376H on NM_138457.3) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV57221653; called by muse, varscan2
- FPGT-TNNI3K | c.845del p.F282Sfs*15 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs751624085; called by mutect2, pindel, varscan2
- FRAS1 | c.3806T>G p.L1269R | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV53627445; called by muse, mutect2, varscan2
- FREM1 | c.4677del p.T1560Qfs*46 | Frame Shift Del (DEL) | VAF 94/317 reads (30%) | catalogued as rs1358593282, COSV66528287; called by mutect2, pindel, varscan2
- FTMT | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.065); catalogued as COSV58420855; called by muse, mutect2, varscan2
- FUT2 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67179534; called by muse, mutect2, varscan2
- FUT9 | c.450C>A p.H150Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.484); catalogued as COSV56151139; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs756304971; called by mutect2, varscan2
- FYB1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs757886197, COSV60940974; called by muse, mutect2, varscan2
- FYCO1 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533441275, COSV56117648; called by muse, mutect2, varscan2
- FZD4 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV72294560; called by muse, mutect2, varscan2
- GAB1 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV53758560; called by muse, mutect2, varscan2
- GABRA2 | c.1235A>G p.N412S | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV62916874; called by muse, mutect2, varscan2
- GABRA6 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1274527420, COSV50884676, COSV50886153; called by muse, mutect2, varscan2
- GABRB1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs78133797, COSV54991113; called by muse, mutect2, varscan2
- GABRG1 | c.792del p.F264Lfs*3 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs772301203; called by mutect2, varscan2
- GAD1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs141910612; called by muse, mutect2, varscan2
- GAD1 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64026760; called by muse, mutect2, varscan2
- GALC | c.1931T>A p.M644K | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54327667; called by muse, mutect2, varscan2
- GALNT10 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 109/319 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as rs762822794, COSV51720527; called by muse, mutect2, varscan2
- GALNT17 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100353459, COSV61174107; called by muse, mutect2, varscan2
- GALNT2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64196239; called by muse, mutect2
- GALNTL6 | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101550718, COSV72553062; called by muse, mutect2, varscan2
- GAN | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 124/505 reads (25%) | catalogued as rs370358470, CM002982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GARNL3 | c.145-2A>G p.X49_splice | Splice Site (SNP) | VAF 17/272 reads (6%) | catalogued as COSV100149896; called by muse, mutect2
- GARNL3 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 74/319 reads (23%) | catalogued as COSV59228404; called by muse, mutect2, varscan2
- GARRE1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV55101428; called by muse, mutect2, varscan2
- GBA | c.762-1G>T p.X254_splice | Splice Site (SNP) | VAF 31/72 reads (43%) | catalogued as CS075151, COSV100516217; called by muse, mutect2, varscan2
- GBA2 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as rs1317345720, COSV62306397; called by muse, mutect2, varscan2
- GBA2 | c.1535A>G p.H512R | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV62305858; called by muse, mutect2
- GBP5 | c.731del p.K244Sfs*13 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | catalogued as rs34148688; called by mutect2, pindel, varscan2
- GBP6 | c.1760del p.N587Mfs*18 | Frame Shift Del (DEL) | VAF 38/205 reads (19%) | catalogued as rs1557544730; called by mutect2, pindel, varscan2
- GCC1 | c.1729C>A p.R577S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV58463148; called by muse, mutect2, varscan2
- GCLC | c.1247del p.P416Lfs*11 (on ENST00000643939; = p.P414Lfs*11 on NM_001498.4) | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as CM077549; called by mutect2, pindel, varscan2
- GCNT4 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs138374806, COSV59281263; called by muse, mutect2, varscan2
- GDF6 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54626352; called by muse, mutect2
- GDI2 | c.890T>C p.V297A | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV60168528; called by muse, mutect2, varscan2
- GEMIN5 | c.336A>G p.I112M | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1220871600, COSV53562476; called by muse, mutect2, varscan2
- GFOD1 | c.814G>C p.A272P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV64954995; called by muse, mutect2
- GGCX | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 90/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52089300; called by muse, mutect2, varscan2
- GIMAP2 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 58/206 reads (28%) | catalogued as rs550994929, COSV56235275; called by muse, mutect2, varscan2
- GJA8 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM166501, COSV53790907, COSV99569031; called by muse, varscan2
- GJA8 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs926855257, COSV99569081; called by muse, varscan2
- GLB1L | c.395del p.G132Vfs*14 | Frame Shift Del (DEL) | VAF 27/165 reads (16%) | catalogued as rs780866249; called by mutect2, pindel, varscan2
- GLI3 | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.948); catalogued as rs1249732177, COSV67891484; called by muse, mutect2, varscan2
- GLRB | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52413745, COSV52419568; called by muse, mutect2, varscan2
- GML | c.98A>T p.D33V | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV55277840; called by muse, mutect2, varscan2
- GMPR2 | c.367G>A p.V123M (on ENST00000355299 / NM_001351022.2; = p.V141M on NM_016576.5) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); catalogued as COSV51661088; called by muse, mutect2, varscan2
- GNAI1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as rs758691743, COSV63523172; called by muse, mutect2, varscan2
- GNAT1 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV50032037; called by muse, mutect2
- GNRHR | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs769336438, COSV56934216; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 43/128 reads (34%) | catalogued as rs763679060; called by mutect2, varscan2
- GOLGA3 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99202240; called by muse, mutect2
- GOLGB1 | c.4972_4974del p.K1658del | In Frame Del (DEL) | VAF 115/498 reads (23%) | catalogued as rs1560230502; called by pindel, varscan2
- GON4L | c.6062A>C p.K2021T | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); catalogued as COSV99673263; called by muse, mutect2, varscan2
- GOSR1 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as rs1199940538, COSV56719849; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 253/313 reads (81%) | catalogued as rs370114090; called by mutect2, varscan2
- GP1BA | c.624del p.F208Lfs*48 | Frame Shift Del (DEL) | VAF 52/254 reads (20%) | catalogued as rs868628165; called by mutect2, pindel, varscan2
- GPR141 | c.691A>T p.I231L | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.095); catalogued as COSV57733133; called by muse, mutect2, varscan2
- GPR158 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs368132351, COSV100893879; called by muse, mutect2, varscan2
- GPR37 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV58258261, COSV58258868; called by muse, mutect2, varscan2
- GPR61 | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.311); catalogued as COSV68177875; called by muse, mutect2, varscan2
- GRAMD2A | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs752466619, COSV59034418; called by muse, mutect2, varscan2
- GRIA2 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52397617; called by muse, mutect2, varscan2
- GRIA2 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99642992; called by muse, mutect2, varscan2
- GRIA3 | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 115/193 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52058519; called by muse, mutect2, varscan2
- GRIK1 | c.2673del p.K891Nfs*6 (on ENST00000327783 / NM_001330994.2; = p.K876Nfs*6 on NM_001330993.2) | Frame Shift Del (DEL) | VAF 76/280 reads (27%) | catalogued as rs747093705; called by pindel, varscan2
- GRIK2 | c.1631A>C p.K544T | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV59752639; called by muse, varscan2
- GRIN2A | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs758117698, COSV58032342; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIP1 | c.1270A>G p.T424A (on ENST00000359742 / NM_001379345.1; = p.T372A on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV99667948; called by muse, mutect2
- GRK3 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV100151065; called by muse, mutect2, varscan2
- GRM5 | c.1068A>T p.Q356H | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV59615200; called by muse, mutect2, varscan2
- GRM8 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs140162343; called by muse, mutect2, varscan2
- GRPR | c.662T>A p.I221N | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66669869; called by muse, mutect2, varscan2
- GSDMA | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.076); catalogued as COSV100053511; called by muse, mutect2
- GSK3B | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51779057; called by muse, mutect2, varscan2
- GSTA1 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58016131; called by muse, mutect2, varscan2
- GTF2E1 | c.1307A>G p.D436G | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.626); catalogued as COSV52205312; called by muse, mutect2, varscan2
- GTF2F1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 160/492 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs146571246; called by muse, mutect2, varscan2
- GTF3C5 | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV59601060; called by muse, mutect2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as COSV54945907; called by mutect2, varscan2
- GZF1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV57637053; called by muse, mutect2, varscan2
- H1-2 | c.400del p.A134Qfs*33 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as COSV59189725; called by mutect2, pindel, varscan2
- H1-2 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201295771, COSV100642238, COSV59192334; called by muse, varscan2
- H1-2 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781062933, COSV100642241, COSV59192424; called by muse, varscan2
- H1-3 | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs774471687, COSV55098065; called by muse, varscan2
- H2AC1 | c.229del p.T77Lfs*10 | Frame Shift Del (DEL) | VAF 22/125 reads (18%) | catalogued as rs778804735, COSV99032261; called by mutect2, pindel, varscan2
- H2AC14 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.23); catalogued as rs1484202795, COSV60798315; called by muse, mutect2, varscan2
- H2AC20 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as COSV100479680; called by muse, mutect2
- H2AC21 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.075); catalogued as rs1553760158, COSV58612603; called by muse, varscan2
- H2AC21 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as rs1014554334, COSV58612607; called by muse, varscan2
- H2BC6 | c.107A>C p.E36A | Missense Mutation (SNP) | VAF 22/339 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV61591435; called by muse, mutect2
- H2BC7 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV61912153; called by muse, mutect2, varscan2
- H4C13 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs1055231776, COSV60694646; called by muse, mutect2, varscan2
- H4C5 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV63487107; called by muse, mutect2, varscan2
- H4C6 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs778148505, COSV66685691; called by muse, mutect2, varscan2
- HAO1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs768341358, COSV66491567; called by muse, mutect2, varscan2
- HAPLN1 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 90/251 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751061353, COSV57149974, COSV57152357; called by muse, mutect2, varscan2
- HAUS1 | c.732A>T p.L244F | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56363724; called by muse, mutect2, varscan2
- HBE1 | c.115A>C p.T39P | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346630562, COSV53080616; called by muse, mutect2, varscan2
- HBS1L | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs777731477, COSV59020988; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | catalogued as rs755844571, COSV63794110; called by mutect2, varscan2
- HDLBP | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs1384832289, COSV60491735; called by muse, mutect2, varscan2
- HEATR5B | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs866587136, COSV51855628; called by muse, mutect2, varscan2
- HECTD1 | c.5398A>G p.T1800A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV101237298; called by muse, mutect2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs57105282; called by mutect2, varscan2
- HELT | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58820243; called by muse, mutect2, varscan2
- HERC2 | c.9917T>G p.L3306* | Nonsense Mutation (SNP) | VAF 50/171 reads (29%) | catalogued as COSV55336029; called by muse, varscan2
- HERC5 | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV52042049; called by muse, mutect2, varscan2
- HERPUD1 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV55862728; called by muse, mutect2, varscan2
- HHIPL2 | c.1891A>T p.T631S | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV100596580; called by muse, mutect2, varscan2
- HIC2 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1226322603, COSV68042538; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 44/182 reads (24%) | catalogued as rs199474609; called by mutect2, varscan2
- HMGN5 | c.534del p.G179Vfs*48 | Frame Shift Del (DEL) | VAF 8/11 reads (73%) | catalogued as rs1556033122; called by mutect2, varscan2
- HNRNPA3 | c.73-1G>T p.X25_splice | Splice Site (SNP) | VAF 15/65 reads (23%) | catalogued as COSV66821015; called by muse, mutect2, varscan2
- HNRNPCL1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772611920, COSV58610457, COSV58613905; called by muse, mutect2, varscan2
- HNRNPL | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1233289638, COSV55493928; called by muse, mutect2, varscan2
- HPX | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs142045379, COSV56421064; called by muse, mutect2, varscan2
- HS2ST1 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1161721585, COSV100085824; called by muse, mutect2
- HSD3B1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 109/427 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV52491457; called by muse, mutect2, varscan2
- HSPA1L | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65150910; called by muse, mutect2, varscan2
- HSPA4L | c.2347A>T p.N783Y | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV56546815; called by muse, mutect2, varscan2
- HTR1F | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.036); catalogued as COSV60390267; called by muse, mutect2, varscan2
- HTR2B | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 27/375 reads (7%) | catalogued as COSV99295140; called by muse, mutect2
- HYDIN | c.7956del p.E2653Kfs*4 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs796610608; called by mutect2, varscan2
- IARS2 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV56961737; called by muse, mutect2, varscan2
- IBTK | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.038); catalogued as COSV60394446; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs747841314; called by mutect2, varscan2
- ICE1 | c.4598A>G p.Q1533R | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV56828670; called by muse, mutect2, varscan2
- IFNA16 | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 128/423 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66509846, COSV66510396; called by muse, mutect2, varscan2
- IFT46 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV50594764; called by muse, mutect2, varscan2
- IFT88 | c.1366A>G p.R456G (on ENST00000319980 / NM_001318493.2; = p.R447G on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV60675151; called by muse, mutect2, varscan2
- IGDCC3 | c.977T>G p.V326G | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60078666; called by muse, mutect2, varscan2
- IGF2BP1 | c.1507A>G p.I503V | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51733535; called by muse, mutect2, varscan2
- IGHV2-70 | c.53T>G p.L18* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as rs546731210; called by muse, mutect2, varscan2
- IGKV1-8 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 129/517 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377382972; called by muse, mutect2
- IGSF10 | c.5207T>C p.V1736A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as rs1233385178, COSV56788376; called by muse, mutect2, varscan2
- IGSF9B | c.1628T>C p.V543A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV58070214; called by muse, mutect2
- IKZF2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.711); catalogued as rs761250260, COSV59580984; called by muse, mutect2, varscan2
- IL12RB2 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1380169444, COSV99254645; called by muse, mutect2
- IL17RC | c.1066A>G p.T356A (on ENST00000295981 / NM_153461.4; = p.T270A on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.292); catalogued as rs767165570, COSV55974121; called by muse, mutect2, varscan2
- IL24 | c.460A>T p.S154C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV54321083; called by muse, mutect2, varscan2
- IL3RA | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58432414; called by muse, mutect2, varscan2
- IL6R | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as COSV59817757; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- ILK | c.172dup p.A58Gfs*11 | Frame Shift Ins (INS) | VAF 18/92 reads (20%) | catalogued as rs770182262; called by mutect2, pindel, varscan2
- INPP5F | c.631del p.W211Gfs*5 | Frame Shift Del (DEL) | VAF 31/101 reads (31%) | catalogued as rs768918635; called by mutect2, pindel, varscan2
- INPP5F | c.1916A>T p.D639V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100739979; called by muse, mutect2, varscan2
- INSC | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs780043285, COSV65411842; called by muse, varscan2
- INSR | c.3924G>T p.E1308D | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV57167215; called by muse, mutect2, varscan2
- INTS2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 88/364 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs554961043, COSV52153889, COSV52154784; called by muse, mutect2, varscan2
- INTS5 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as rs749822254, COSV57952527; called by muse, mutect2, varscan2
- INTS6 | c.1637A>G p.D546G | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60878507; called by muse, mutect2, varscan2
- INTS8 | c.2954del p.K985Sfs*44 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs1352150703; called by mutect2, varscan2
- INVS | c.2336G>A p.R779Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); catalogued as rs771128055, COSV52445696; called by muse, mutect2, varscan2
- IPO11 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57578554; called by muse, mutect2, varscan2
- IPO13 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV64894008; called by muse, mutect2, varscan2
- IQCA1 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs370743777; called by muse, mutect2
- IQCB1 | c.1333C>G p.R445G | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as CM1211312, COSV60438349; called by muse, mutect2, varscan2
- IQGAP3 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63253101, COSV63255276; called by muse, mutect2, varscan2
- IQSEC1 | c.2666A>G p.Q889R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as COSV56226157; called by muse, mutect2
- IRAK2 | c.1613A>T p.D538V | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV56533432; called by muse, mutect2, varscan2
- IRF6 | c.301A>G p.K101E | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV65419809; called by muse, mutect2, varscan2
- IRS1 | c.136T>A p.Y46N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59337598; called by muse, mutect2
- IRX1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs957560853, COSV57360869; called by muse, mutect2, varscan2
- ISL1 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV57934610; called by muse, mutect2, varscan2
- ISL1 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57934619; called by muse, mutect2, varscan2
- ITGA6 | c.3351del p.K1117Nfs*? (on ENST00000442250; = p.K1078Nfs*48 on NM_001079818.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs201055917; ClinVar: uncertain significance; called by mutect2, varscan2
- ITGAM | c.2255T>C p.V752A (on ENST00000648685 / NM_001145808.2; = p.V751A on NM_000632.4) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV54939575; called by muse, mutect2, varscan2
- ITGB1 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 93/402 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs201856355, COSV56484096; called by muse, mutect2, varscan2
- ITGB1BP1 | c.150A>G p.S50= | Splice Region (SNP) | VAF 36/168 reads (21%) | catalogued as COSV53006731; called by muse, mutect2
- ITGB3 | c.2071G>A p.V691I | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs534325095, COSV71383530; called by muse, mutect2, varscan2
- ITGB7 | c.1418T>G p.L473R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.678); catalogued as COSV99913906; called by muse, mutect2
- ITGB8 | c.1261A>G p.N421D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.555); catalogued as COSV99750539; called by muse, mutect2
- ITIH5 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs749743981, COSV53669740; called by muse, mutect2, varscan2
- ITIH5 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs368025989; called by muse, mutect2, varscan2
- ITPR1 | c.2915A>G p.K972R (on ENST00000354582; = p.K957R on NM_002222.7) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56992245; called by muse, mutect2, varscan2
- ITPR2 | c.3203A>G p.D1068G | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV101189805; called by muse, mutect2, varscan2
- ITPRIP | c.307T>C p.W103R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV53392366; called by muse, mutect2, varscan2
- JARID2 | c.2020C>T p.L674F | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV59192962; called by muse, mutect2, varscan2
- JARID2 | c.2993A>G p.H998R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.871); catalogued as COSV59192969; called by muse, mutect2
- JPH1 | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.565); catalogued as COSV60612751; called by muse, mutect2, varscan2
- JPT2 | c.171A>G p.I57M | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV99935960; called by muse, mutect2
- KALRN | c.7057G>A p.V2353I (on ENST00000360013 / NM_001024660.4; = p.V656I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs774580265, COSV52258250; called by muse, mutect2, varscan2
- KANSL1 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 87/530 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs983743854, COSV52271120; called by muse, mutect2
- KAT5 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV57730135; called by muse, mutect2
- KBTBD12 | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59680493; called by muse, mutect2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 99/322 reads (31%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
1,890 further variants in this file (1,303 protein-altering or splice-affecting, 538 silent, 49 other) are not listed here.
